Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A3DW, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A3DW-01A (Primary Tumor).

	hw	10/21/11

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

THYROID (TOTAL THYROIDECTOMY): PAPILLARY THYROID CARCINOMA, TALL CELL VARIANT, INVOLVING THE RIGHT LOBE (2.7 CM). THE TUMOR INVOLVES THE THYROID CAPSULE BUT DOES NOT EXTEND BEYOND THE THYROID. THE TUMOR EXTENDS TO THE MARGIN. METASTATIC PAPILLARY THYROID CARCINOMA IN ONE (1) PERITHYROIDAL LYMPH NODE. THE PATHOLOGIC STAGE IS T2N1MX.

Part# 1: TOTAL THYROIDECTOMY ~ The specimen is received fresh labeled with the patient's name and designated as total thyroidectomy. It consists of a grossly recognizable thyroid, measuring 6 x 6 x 2.5 cm and weighing 6.87 gm. The specimen is opened and examined by Dr. ' prior to my receiving the specimen. In the right lobe (marked with a stitch), is a well-circumscribed, tan, homogeneous tumor, measuring 2.7 cm in diameter. Otherwise, the gland is normal. Representative sections are submitted. ~
~ SUMMARY OF SECTIONS ~ 1 - A- 3 (LEFT NORMAL LOBE) ~ 1 - B- 2 (PYRAMIDAL LOBE) ~ 1 - C- 2 (TUMOR) ~ 1 - D- 3 (TUMOR) ~ 1 - E- 3 (TUMOR) ~ 1 - F- 1 (TUMOR) ~ 1 - G- 3 (TUMOR) ~ 1 - H- 1 (TUMOR) ~ 8 - TOTAL- M (NOTE: SEVENTY PERCENT OF THE SPECIMEN IS SUBMITTED, 90% OF TUMOR). ~

1CB-0-3

carcinoma, papillary, tall cell variant 8344/3

Site: thyroid, NOS C73.9

hw
10/21/11

Source: NCI Genomic Data Commons file c291d275-70a6-4e4a-97e3-ec8615e1d6d7 (TCGA-ET-A3DW.3845B33D-DBAD-4C9A-A98B-9EE28EE7A4C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).